Somatic mutation profile of tumor specimen TCGA-J8-A42S-01A (aliquot TCGA-J8-A42S-01A-11D-A23M-08) from TCGA case TCGA-J8-A42S, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 45.5 years (16,609 days).
Specimen TCGA-J8-A42S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b39a65d-507b-4257-911c-f52f94fa358b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A42S-10A (Blood Derived Normal), aliquot TCGA-J8-A42S-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/784c193b-76c5-4705-84d5-5096a552aab9

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CPNE1 | c.223C>T p.R75C (on ENST00000352393; = p.R80C on NM_003915.5) | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs747677512, COSV100467376; called by muse, mutect2
- DNAH17 | c.11417C>G p.S3806W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101102065, COSV67749318; called by muse, mutect2, varscan2
- DNAH3 | c.6344T>A p.I2115N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99766803; called by muse, mutect2, varscan2
- NID2 | c.1096A>T p.K366* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99356359; called by muse, mutect2, varscan2
- SZT2 | c.4069C>T p.P1357S (on ENST00000634258 / NM_001365999.1; = p.P1300S on NM_015284.4) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.236); catalogued as rs748826670, COSV100987174; called by muse, mutect2, varscan2
- TAF2 | c.3383G>A p.S1128N | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100978619; called by muse, mutect2, varscan2
- CDH15 | c.687C>T p.T229= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99228286; called by muse, mutect2
- GSDME | c.762C>T p.Y254= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV100742310; called by muse, mutect2, varscan2
